Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A965, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A965-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 10.0 x 8.0 x 5.0 cm

focal infiltration of capsule and lung parenchyma

Diagnosis:

Type A-Thymoma

pT3, pNx

Masaoka-Koga: III

Immunohistochemistry

epithelial cells positive for: CK5/6, KL1

some CD99-, TdT-positive immature T-lymphocytes

ICD-O-3

Thymoma, type A, malignant
858113

Site Thymus
C379

4/7/14

DQ - Prior malignancy with
UNKNOWN systemic therapy -
w/ 11/01/14

Prior Malignancy History	uterine ✓	✓
Case is (circled) / DISQUALIFIED		

Source: NCI Genomic Data Commons file 214029a0-664a-4219-98cf-0ae65fff1dad (TCGA-ZB-A965.ECAA1C00-E3DF-49B9-A623-5269D81F8C17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).